TCGA case TCGA-V1-A8WS — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland; Tissue source site: University of California San Francisco. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bea84d33-3286-44e2-9595-893c34a01f58

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Method of diagnosis: Core Biopsy; AJCC clinical T: T1c; AJCC clinical M: M0; AJCC pathologic T: T3b; Primary gleason grade: Pattern 3; Secondary gleason grade: Pattern 3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Gleason score: 6.
   Pathology details: Consistent pathology review: Yes; Tumor level prostate: Apex; Zone of origin prostate: Peripheral zone.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS, for biochemical recurrence; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Timepoint: Post Initial Treatment.
- Follow-up contact recording only the day: day 474.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0.09 ng/mL (day 474).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-V1-A8WS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 30 mg.
  Slide TCGA-V1-A8WS-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 70; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-V1-A8WS-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-V1-A8WS-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Method initial path diagnosis: Core needle biopsy; Ct scan ab pelvis indicator: No; Diagnostic mri performed: No; Lymph nodes examined: No; Biochemical recurrence indicator: No; New tumor event diagnosis indicator: Yes.
- Tumor levels: Tumor level: Apex.
- Stage record, Psa: PSA most recent results: 0.09.
- Stage record, Gleason grading: Gleason pattern primary: 3; Gleason pattern secondary: 3.
- New tumor event: New tumor event type: Biochemical evidence of disease; Progression after hormone treatment: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Progressive Disease; Treatment outcome at TCGA followup: Partial Remission/Response; New tumor event diagnosis indicator: Yes; New tumor event type: Biochemical evidence of disease; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 474 days; disease-specific survival: no event (censored), 474 days; progression-free interval: no event (censored), 474 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-V1-A8WS-01A-11D-A376-01): tumor purity 0.77, ploidy 1.96, whole-genome doublings 0.
